Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9H5, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9H5-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

ICD-O-3
Carcinoma, hepatocellular
NOS 8170.3
Site: Liver C22.0
QID 4/28/14

Final Diagnosis

- A GALLBLADDER, EXCISION:
- Chronic cholecystitis
- B LIVER, HEPATIC SEGMENTS 5 AND 6, RESECTION:
- Hepatocellular carcinoma.
- See key pathologic findings.
- Surgical margins are not involved.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed
Out by _____

Ancillary Studies

Immunostains with adequate controls are positive for alpha-fetoprotein, HepPar1 (focal), MUC1 (focal), pCEA (focal) and MOC-31. The polyclonal CEA does not show unequivocal evidence of intercellular canalicular pattern. Additionally, the tumor cells are negative for CK7, CK20, CD10, MUC-5, WT-1, calcitonin, TTF-1, thyroglobulin, p63, MUC-2, ER, synaptophysin, chromogranin, CD56, CDX2, and inhibin. The findings are consistent with a hepatocellular carcinoma.

On the uninvolved liver parenchyma, the trichrome, reticulin stains show portal expansion and focal bridging fibrosis. The PAS and PAS with diastase are unremarkable. The Iron stain does not show abnormal iron deposits.

Key Pathological Findings

Tumor size: 9.0 x 7.0 x 5.0 cm
Histologic type: hepatocellular carcinoma
Histologic grade: grade 2 (Edmondson and Steiner grading system)
Tumor necrosis: absent
Extent of invasion: absent
Perineural invasion: absent
Parenchymal margin: Uninvolved
Venous (large vessel) invasion: absent
Tumor at 1.5 cm from surgical margin.
Additional pathologic findings:
Portal inflammation with minimal lobular involvement, compatible with chronic hepatitis, grade 1
Portal expansion with focal bridging fibrosis, compatible with stage 2
Iron overload: absent
Lymph nodes: not applicable
Pathologic stage: pT1, pNX

Specimen(s) Received

- A NORMAL GALLBLADDER
B HEPATIC SEGMENT 5 AND 6 FS

[page 2 of 2]
Hepatitis now with hepatocellular carcinoma.

Hepatocellular carcinoma.

FSB. HEPATIC SEGMENT 5 AND 6 :
Inked margin free of tumor.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by _____ in _____ at _____

Gross Description

A. The specimen is labeled "normal gallbladder". The specimen is received fresh and consists of a club-shaped gallbladder measuring 11.0 x 3.5 x 2.5 cm. The external surface is tan-pink, smooth on 1 aspect and roughened on the opposite aspect. The cystic duct is identified measuring 0.5 cm in length. On opening the specimen contains a small amount of green visceral bile. The mucosal surface is green-yellow and velvet-like. No calculi are grossly identified. No tissue is submitted to the Tissue Procurement Laboratory. Representative sections are submitted as A1.

B. The specimen is received fresh for our consult labeled "hepatic segment No. 5 and 6, frozen section". The specimen consists of a 271.3 gram, 11.0 x 10.5 x 5.5 cm resected segment of liver. The surgical margin resection is marked with black ink. A palpable mass is grossly identified with possible gross involvement of the overlying capsule (blue ink). Serial sections reveal an indurated, gray-white, well-demarcated intraparenchymal mass (9.0 x 7.0 x 5.0 cm). The tumor comes to within 1.5 cm of the surgical margin of resection grossly. A representative section of the tumor showing its relationship to the surgical margin of resection is submitted on frozen section as FSB1. There is gross evidence of a blood clot located at the surgical margin of resection. The remainder of the cut surface exhibits grossly unremarkable hepatic parenchyma. A representative section of the tumor is submitted to the Tissue Procurement Laboratory. Permanent representative sections are submitted as:

- B2: Mirror image of tumor submitted to Tissue Bank
B3: Tumor showing its relationship to overlying capsule
B4: Tumor showing its relationship to adjacent parenchyma
B5-B7: Additional sections of tumor
B8: Possible blood clot
B9: Grossly unremarkable parenchyma.

Source: NCI Genomic Data Commons file 932f62f2-3e05-4f14-974f-c614be46ee89 (TCGA-2Y-A9H5.99FC2CC9-19F1-4BCB-81E6-5FED4619B331.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).